Somatic mutation profile of tumor specimen C3N-02066-01 (aliquot CPT0109800007) from CPTAC case C3N-02066, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 61.3 years (22,385 days).
Specimen C3N-02066-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f1b88aa-6b22-416b-8978-cb122e1ed396.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02066-71 (Blood Derived Normal), aliquot CPT0139350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/966faf37-e658-4d8b-a979-41a873528b98

The open-access MAF lists 82 somatic variants for this specimen: 61 protein-altering or splice-affecting, 10 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 10, Frame Shift Del 5, 3'UTR 4, Intron 3, Nonsense Mutation 2, In Frame Del 2, Frame Shift Ins 2, RNA 2, Splice Site 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLDN16 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772241737, CM1312164, COSV53228138; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.227_229del p.F76del | In Frame Del (DEL) | VAF 114/437 reads (26%) | hotspot (GDC flag); catalogued as rs5030648; called by pindel, varscan2
- ADGRV1 | c.9476C>T p.T3159M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs374467239; called by muse, mutect2, varscan2
- ADRA1B | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs778832771; called by muse, mutect2, varscan2
- ARHGAP26 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50829120; called by muse, mutect2, varscan2
- ARHGAP36 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs370581558; called by muse, varscan2
- BAZ2A | c.1583T>A p.I528N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.023); catalogued as rs370773408; called by muse, mutect2, varscan2
- F2RL2 | c.512dup p.I172Hfs*76 | Frame Shift Ins (INS) | VAF 29/214 reads (14%) | catalogued as rs766441953; called by mutect2, pindel, varscan2
- KLHDC7B | c.694C>G p.Q232E (on ENST00000395676; = p.Q873E on NM_138433.5) | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs764159392; called by muse, mutect2, varscan2
- LRP6 | c.3637G>A p.G1213S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53792106; called by muse, mutect2, varscan2
- MAP2 | c.3530C>T p.P1177L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.023); catalogued as COSV52305327; called by muse, mutect2, varscan2
- MLF1 | c.29A>C p.E10A | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV63034215; called by muse, mutect2, varscan2
- NCKAP5L | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs770524990, COSV100259159; called by muse, mutect2, varscan2
- PATL2 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as rs901718736, COSV71384460; called by muse, mutect2, varscan2
- PDGFRA | c.2968G>A p.G990S | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.984); catalogued as COSV57273636; called by muse, mutect2, varscan2
- PRKCZ | c.1293C>A p.S431R | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66071702; called by muse, mutect2, varscan2
- SLC17A8 | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.347); catalogued as COSV60125333; called by muse, mutect2, varscan2
- SNRPN | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57601523; called by muse, mutect2, varscan2
- TAF2 | c.2269A>G p.M757V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as rs1192237770; called by muse, varscan2
- ZNF253 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs763411661; called by muse, mutect2, varscan2
- ZNF516 | c.3367G>C p.V1123L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV101487329; called by muse, mutect2, varscan2
- AC244197.3 | c.312G>T p.L104F | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKAP11 | c.5620G>T p.V1874L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- AL662899.2 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATAD2B | c.1083G>T p.L361F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C3AR1 | c.1333_1344del p.K445_Q448del | In Frame Del (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel, varscan2
- CDIP1 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPJ | c.1124T>A p.F375Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CFAP99 | c.842del p.K281Rfs*5 | Frame Shift Del (DEL) | VAF 102/444 reads (23%) | called by mutect2, pindel, varscan2
- CPSF1 | c.242T>A p.M81K | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CSMD2 | c.1080-1G>T p.X360_splice | Splice Site (SNP) | VAF 56/171 reads (33%) | called by muse, mutect2, varscan2
- CTNNBL1 | c.566T>A p.V189E | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- DCLRE1C | c.1968_1969del p.P657Rfs*3 (on ENST00000378278 / NM_001350965.2; = p.P542Rfs*3 on NM_022487.4) | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- DIAPH1 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 144/392 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, varscan2
- DNHD1 | c.5845T>G p.Y1949D | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM219A | c.245A>C p.N82T (on ENST00000445726; = p.N65T on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FRAS1 | c.7033_7034insGG p.E2345Gfs*34 | Frame Shift Ins (INS) | VAF 10/76 reads (13%) | called by mutect2, pindel
- GCC1 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- GOLGB1 | c.5196A>T p.K1732N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GPR135 | c.171C>A p.D57E | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GREM1 | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 85/316 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- HES6 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 27/168 reads (16%) | called by muse, mutect2, varscan2
- IGHG2 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 57/265 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LETMD1 | c.1046T>C p.V349A | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MINAR1 | c.19del p.T7Lfs*6 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- MTHFD1L | c.2561G>T p.R854L | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- NDST3 | c.1568A>C p.N523T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- NUP188 | c.842C>A p.S281Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- PAQR5 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.078); called by muse, varscan2
- PCDHB3 | c.341T>C p.L114S | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- PRKDC | c.7802T>C p.V2601A | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RASGEF1C | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RASGRP3 | c.793T>G p.S265A | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RIMS1 | c.289A>G p.K97E | Missense Mutation (SNP) | VAF 102/399 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SEPTIN2 | c.779G>T p.W260L | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TAB3 | c.1099_1100del p.E367Nfs*4 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by pindel, varscan2
- TOX3 | c.1112C>A p.S371* | Nonsense Mutation (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- WASHC2C | c.3620A>G p.D1207G (on ENST00000336378; = p.D1186G on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ZDHHC21 | c.464G>T p.C155F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF709 | c.1115C>A p.A372D | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZSCAN16 | c.818del p.F273Sfs*17 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- ACTC1 | c.666C>T p.A222= | Silent (SNP) | VAF 66/247 reads (27%) | called by muse, mutect2, varscan2
- HERC1 | c.1726C>T p.L576= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- KRT19 | c.999C>G p.A333= | Silent (SNP) | VAF 107/351 reads (30%) | called by muse, mutect2, varscan2
- ODC1 | c.18T>C p.N6= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs1469344787; called by muse, mutect2, varscan2
- RBM24 | c.93C>T p.F31= | Silent (SNP) | VAF 115/477 reads (24%) | called by muse, mutect2, varscan2
- RERE | c.858T>C p.I286= | Silent (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- SPHK2 | c.1227G>A p.P409= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as rs753083611, COSV55337865; called by muse, mutect2, varscan2
- TET2 | c.4116T>G p.T1372= | Silent (SNP) | VAF 35/167 reads (21%) | catalogued as COSV54403657; called by muse, mutect2, varscan2
- TRPC1 | c.858A>C p.L286= (on ENST00000476941 / NM_001251845.2; = p.L252= on NM_003304.4) | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- ZNF500 | c.741C>T p.D247= | Silent (SNP) | VAF 44/189 reads (23%) | catalogued as rs761080594; called by muse, mutect2, varscan2
- AC092865.4 | chr12:8390696 C>T | 5'Flank (SNP) | VAF 18/110 reads (16%) | called by muse, varscan2
- C20orf197 | n.446T>A | RNA (SNP) | VAF 24/67 reads (36%) | called by muse, varscan2
- CDCA7 | c.147+614C>A | Intron (SNP) | VAF 23/90 reads (26%) | catalogued as COSV60720444; called by muse, mutect2, varscan2
- ILF3 | c.*251_*252insAA | 3'UTR (INS) | VAF 62/294 reads (21%) | called by mutect2, pindel
- LILRB5 | c.-1C>A | 5'UTR (SNP) | VAF 70/253 reads (28%) | called by muse, mutect2, varscan2
- MLXIPL | c.573+52G>A | Intron (SNP) | VAF 16/83 reads (19%) | catalogued as rs781790202; called by muse, mutect2
- PARP8 | c.2378-39G>T | Intron (SNP) | VAF 13/37 reads (35%) | called by muse, varscan2
- RAB18 | c.*347C>A | 3'UTR (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*1259G>A | 3'UTR (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- TUBB2B | c.*15C>T | 3'UTR (SNP) | VAF 34/197 reads (17%) | catalogued as rs750457664, COSV52533747; called by muse, mutect2, varscan2
- ZNF503-AS2 | n.622G>A | RNA (SNP) | VAF 97/508 reads (19%) | called by muse, varscan2
